Gene-level copy-number profile of tumor specimen TCGA-VS-A9UT-01A from TCGA case TCGA-VS-A9UT, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 72.8 years (26,603 days).
Specimen TCGA-VS-A9UT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.4b26fba7-3ae2-4fd4-be8b-8fb9cdf5fc85.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A9UT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/609f95e0-45a2-42d1-8dc7-edcef972066f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 19,089; copy number 2: 37,612; copy number 3: 2,802; copy number 6: 55; copy number 7: 84; copy number 9: 90; copy number 17: 70.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A9UT-01A-11D-A42N-01): tumor purity 0.45, ploidy 1.7, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:7,513,298–7,905,955, 15 genes (within-gene range 0–1): PPFIBP2, AC107884.2, CYB5R2, OVCH2, AC104237.2, AC104237.3, AC044810.3, AC104237.1, OR10AB1P, OR5P4P, AC044810.2, OR5P1P, AC044810.1, OR5P2, OR5P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 228 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:21,900,899–32,761,787, 228 genes, copy number 6–17 (within-gene range 2–17) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19,089. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
